Somatic mutation profile of tumor specimen C3L-06641-03 (aliquot CPT0358590006) from CPTAC case C3L-06641, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 76.1 years (27,780 days).
Specimen C3L-06641-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0525c544-09ae-40ef-afcf-bfc5a71d6c72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06641-31 (Blood Derived Normal), aliquot CPT0358680005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d36353ae-b574-4481-9b7b-bfef7af2a149

The open-access MAF lists 93 somatic variants for this specimen: 66 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 25, Nonsense Mutation 4, Intron 2, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.4749C>T p.Y1583= | Splice Region (SNP) | VAF 94/480 reads (20%) | catalogued as rs1015433570; called by muse, mutect2
- AMY2B | c.199C>A p.H67N | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100796203; called by muse, mutect2
- BCLAF3 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 62/185 reads (34%) | catalogued as COSV100503328; called by muse, mutect2, varscan2
- CILP2 | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs776235401; called by muse, mutect2
- DDX4 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.185); catalogued as rs987029382; called by muse, mutect2, varscan2
- DNAH9 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV52355244; called by muse, mutect2, varscan2
- DYRK2 | c.640C>T p.P214S (on ENST00000344096 / NM_006482.3; = p.P141S on NM_003583.4) | Missense Mutation (SNP) | VAF 158/803 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.351); catalogued as rs1391210769; called by muse, mutect2, varscan2
- GML | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55276286; called by muse, mutect2, varscan2
- IRS2 | c.2760C>G p.I920M | Missense Mutation (SNP) | VAF 37/1210 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101018798; called by muse, mutect2
- KCNH2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1060500663, COSV51125839, COSV51215370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIPG | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs756501637, COSV54296849; called by muse, mutect2, varscan2
- MYT1L | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 44/439 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs759081053, COSV67732186; called by muse, varscan2
- NIN | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs140133644, COSV55403275; called by muse, mutect2
- NKD2 | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 77/657 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV56893824; called by muse, mutect2, varscan2
- NYAP2 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs753357006, COSV56002010; called by muse, mutect2, varscan2
- NYX | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100699519; called by muse, mutect2, varscan2
- OR2B11 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 165/509 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.561); catalogued as rs769171531, COSV59510103; called by muse, mutect2
- PLA2G6 | c.1268C>A p.A423E | Missense Mutation (SNP) | VAF 45/435 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs199636953; called by muse, mutect2, varscan2
- PSMA8 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100378826; called by mutect2, varscan2
- PTPRG | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs560692180, COSV55627438; called by muse, mutect2, varscan2
- RPIA | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as rs367917981; called by muse, mutect2, varscan2
- SELENOO | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763930780; called by muse, mutect2, varscan2
- SLC39A4 | c.1213G>C p.A405P (on ENST00000301305 / NM_001374839.1; = p.A380P on NM_017767.3) | Missense Mutation (SNP) | VAF 29/704 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs946034069; called by muse, mutect2
- SLCO4C1 | c.1223T>A p.F408Y | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV60514389; called by muse, mutect2, varscan2
- TMPRSS12 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs200318100; called by muse, mutect2
- ZNF609 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 57/604 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs765084594; called by muse, mutect2
- ZNF735 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 96/518 reads (19%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.986); catalogued as COSV70035325, COSV70036021; called by muse, mutect2, varscan2
- ZNF860 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs767174163; called by muse, mutect2
- ADAM20 | c.1984T>C p.Y662H | Missense Mutation (SNP) | VAF 69/458 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASH1L | c.5216C>T p.A1739V | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- BTBD1 | c.775G>C p.V259L | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2
- CD244 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CDH9 | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COIL | c.1523_1524del p.Q508Pfs*20 | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | called by mutect2, pindel, varscan2
- COL22A1 | c.1202A>G p.K401R | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.232); called by muse, mutect2
- DHX38 | c.3526A>T p.M1176L | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIP2C | c.1173T>G p.N391K | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by mutect2, varscan2
- ELMOD1 | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ELOF1 | c.129_130insT p.N44* | Frame Shift Ins (INS) | VAF 97/432 reads (22%) | called by mutect2, pindel, varscan2
- FHOD3 | c.4153G>T p.E1385* (on ENST00000359247 / NM_001281739.3; = p.E1402* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 66/390 reads (17%) | called by muse, mutect2, varscan2
- FLT4 | c.2653G>T p.A885S | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GASK1B | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GFRA2 | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 21/653 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- GSK3B | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HMBS | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2
- HNRNPCL2 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 36/642 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); called by muse, mutect2
- IFI27 | c.352A>T p.I118F | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- KDM4E | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 93/443 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD5 | c.725A>C p.D242A | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC5B | c.8879A>T p.E2960V | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- P2RY4 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPDC1 | c.2065T>G p.L689V (on ENST00000375360 / NM_177995.3; = p.L741V on NM_152422.4) | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPN23 | c.2108C>G p.A703G | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RARG | c.1346G>A p.G449D | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1CC1 | c.1329A>T p.E443D | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RCBTB2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, varscan2
- RGSL1 | c.3200A>G p.Q1067R | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2
- S100B | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- SEMG2 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 32/376 reads (9%) | called by muse, mutect2
- SEZ6L2 | c.1010C>G p.S337C (on ENST00000308713 / NM_001114099.3; = p.S267C on NM_012410.4) | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.277); called by muse, mutect2
- SPTA1 | c.7219T>A p.Y2407N | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- TMEM232 | c.1201T>G p.S401A | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.269); called by muse, mutect2
- TUBB | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 127/491 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- WDR17 | c.1021T>A p.S341T | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZC3H12A | c.1620_1643del p.R540_G547del | In Frame Del (DEL) | VAF 71/475 reads (15%) | called by mutect2, pindel, varscan2
- ZNF462 | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 70/348 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH26 | c.1635G>A p.A545= | Silent (SNP) | VAF 65/345 reads (19%) | catalogued as COSV54855182; called by muse, mutect2, varscan2
- CFAP46 | c.2172C>T p.S724= | Silent (SNP) | VAF 28/425 reads (7%) | catalogued as rs774029915; called by muse, mutect2
- CPLANE1 | c.180A>C p.I60= (on ENST00000425232; = p.I132= on NM_023073.3) | Silent (SNP) | VAF 12/327 reads (4%) | called by muse, mutect2
- DNAH11 | c.6078C>T p.I2026= | Silent (SNP) | VAF 54/386 reads (14%) | catalogued as rs769000578, COSV100180322; called by muse, mutect2, varscan2
- DYRK2 | c.960C>T p.F320= (on ENST00000344096 / NM_006482.3; = p.F247= on NM_003583.4) | Silent (SNP) | VAF 344/1083 reads (32%) | catalogued as rs1001100183, COSV100165309; called by muse, mutect2, varscan2
- DYRK2 | c.1149C>T p.I383= (on ENST00000344096 / NM_006482.3; = p.I310= on NM_003583.4) | Silent (SNP) | VAF 395/1176 reads (34%) | called by muse, mutect2, varscan2
- FAM126A | c.796A>C p.R266= | Silent (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- FUT6 | c.546G>A p.P182= | Silent (SNP) | VAF 56/483 reads (12%) | catalogued as rs766188766; called by muse, mutect2, varscan2
- GRK2 | c.2004G>A p.P668= | Silent (SNP) | VAF 61/1262 reads (5%) | catalogued as rs945181156, COSV100398441, COSV57754285; called by muse, mutect2
- IGHMBP2 | c.2058T>C p.A686= | Silent (SNP) | VAF 62/1129 reads (5%) | called by muse, mutect2
- IRS2 | c.2901C>T p.S967= | Silent (SNP) | VAF 808/1239 reads (65%) | called by muse, mutect2, varscan2
- KCNK3 | c.786G>A p.A262= | Silent (SNP) | VAF 33/473 reads (7%) | catalogued as COSV57194565; called by muse, mutect2
- KIRREL1 | c.2235C>T p.Y745= | Silent (SNP) | VAF 32/388 reads (8%) | catalogued as rs370865476; called by muse, mutect2
- MAGEC1 | c.99T>C p.S33= | Silent (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
- MAP1A | c.1638G>T p.L546= | Silent (SNP) | VAF 52/481 reads (11%) | called by muse, mutect2, varscan2
- NLRC4 | c.759C>T p.F253= | Silent (SNP) | VAF 79/290 reads (27%) | called by muse, mutect2, varscan2
- NLRP10 | c.1164C>T p.Y388= | Silent (SNP) | VAF 66/579 reads (11%) | catalogued as rs140749197; called by muse, mutect2, varscan2
- NOTCH1 | c.1380G>A p.P460= | Silent (SNP) | VAF 63/473 reads (13%) | catalogued as rs368963607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP188 | c.4981C>T p.L1661= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as rs1461455819; called by muse, mutect2
- RNF145 | c.648C>T p.A216= (on ENST00000424310 / NM_001199383.2; = p.A244= on NM_144726.2) | Silent (SNP) | VAF 98/317 reads (31%) | called by muse, mutect2, varscan2
- SDK1 | c.6498G>A p.A2166= | Silent (SNP) | VAF 51/479 reads (11%) | catalogued as rs778396777, COSV67360806; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.402C>T p.D134= | Silent (SNP) | VAF 42/409 reads (10%) | catalogued as rs746331918; called by muse, varscan2
- TIMELESS | c.1650A>T p.P550= | Silent (SNP) | VAF 58/690 reads (8%) | catalogued as rs186279175; called by muse, mutect2
- TTC26 | c.1293C>A p.L431= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- USH2A | c.5889C>T p.V1963= | Silent (SNP) | VAF 43/248 reads (17%) | catalogued as rs558615453; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2174G>A | Intron (SNP) | VAF 124/622 reads (20%) | called by muse, mutect2, varscan2
- SYT14 | c.226+2617T>C | Intron (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
